Somatic mutation profile of tumor specimen TCGA-BP-4965-01A (aliquot TCGA-BP-4965-01A-01D-1462-08) from TCGA case TCGA-BP-4965, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.5 years (16,992 days).
Specimen TCGA-BP-4965-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4328faec-8f77-4f4a-b186-a6e2c3e2dd64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4965-11A (Solid Tissue Normal), aliquot TCGA-BP-4965-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea57d6d2-60d2-4a05-9181-f80131f65a05

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASL | c.1343T>A p.V448D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59189669; called by muse, mutect2, varscan2
- ATP2A2 | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV58048176; called by muse, mutect2, varscan2
- ATR | c.7411C>A p.L2471M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63393526; called by muse, mutect2, varscan2
- CACYBP | c.135A>T p.Q45H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV62881705; called by muse, mutect2, varscan2
- CCDC178 | c.1195G>T p.V399F | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55763607, COSV55800873; called by muse, mutect2, varscan2
- CES1 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090802; called by muse, mutect2, varscan2
- COMMD10 | c.69T>A p.N23K | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57241754; called by muse, mutect2, varscan2
- COPB2 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV60814047; called by muse, mutect2, varscan2
- DCTN1 | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV62621655; called by muse, mutect2, varscan2
- DOCK3 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV56553637; called by muse, mutect2, varscan2
- EXOC3L1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV52048646; called by muse, mutect2, varscan2
- HERC5 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.034); catalogued as COSV52045750; called by muse, mutect2, varscan2
- HFM1 | c.2768T>G p.L923R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54038589; called by muse, mutect2, varscan2
- IGLV3-25 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs374596533; called by muse, varscan2
- KLK12 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51579155; called by muse, mutect2, varscan2
- KNTC1 | c.1747A>C p.M583L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV61085034; called by muse, mutect2, varscan2
- MT1H | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV60091744; called by muse, mutect2, varscan2
- MUC16 | c.25244C>G p.T8415S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.07); catalogued as COSV67499215; called by muse, mutect2, varscan2
- MUC17 | c.13195del p.V4399Sfs*3 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as COSV60300164; called by mutect2, pindel, varscan2
- MUSK | c.1808T>A p.F603Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51898565; called by muse, mutect2, varscan2
- NAT8 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1456463790, COSV55543123; called by muse, mutect2, varscan2
- OIP5 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52973858; called by muse, mutect2, varscan2
- P2RX7 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV55858137; called by muse, mutect2, varscan2
- PDZD2 | c.7995G>A p.M2665I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56875073; called by muse, mutect2, varscan2
- PGK1 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV64832952; called by muse, mutect2, varscan2
- PNPLA8 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs373363815, COSV57555197; called by muse, mutect2, varscan2
- PRKCB | c.1789C>G p.H597D | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57804990; called by muse, mutect2, varscan2
- PRKCD | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57852154; called by muse, mutect2, varscan2
- RNF213 | c.13304G>A p.S4435N | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60410498; called by muse, mutect2, varscan2
- SLC26A1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56107264; called by muse, mutect2
- SLC47A1 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54504561; called by muse, mutect2, varscan2
- SPG11 | c.5843T>C p.I1948T | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV56003066; called by muse, mutect2, varscan2
- SRCAP | c.8984C>G p.T2995S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV52682347; called by muse, mutect2, varscan2
- TH | c.458G>A p.R153Q (on ENST00000381178 / NM_199292.3; = p.R122Q on NM_000360.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201093528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIE1 | c.2489G>C p.S830T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65251683; called by muse, mutect2, varscan2
- TIPIN | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs781378167, COSV56021254; called by muse, varscan2
- TRPM5 | c.2376C>A p.D792E | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV50210568; called by muse, mutect2, varscan2
- VHL | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BCL2L10 | c.490del p.D164Mfs*29 | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | called by pindel, varscan2
- CCDC174 | c.1138_1153del p.S380Rfs*75 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- COL11A1 | c.1663dup p.S555Kfs*3 | Frame Shift Ins (INS) | VAF 37/172 reads (22%) | called by mutect2, pindel, varscan2
- CUL3 | c.1745_1746dup p.T583* | Frame Shift Ins (INS) | VAF 41/200 reads (21%) | called by mutect2, pindel, varscan2
- ACAN | c.1620C>T p.S540= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV61370721; called by muse, mutect2, varscan2
- ANKMY1 | c.2442G>A p.R814= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV56042066; called by muse, mutect2
- CUL7 | c.1224T>C p.P408= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV54822798; called by muse, mutect2, varscan2
- CUL9 | c.2055G>T p.V685= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV52735858; called by muse, mutect2, varscan2
- GNB2 | c.897C>T p.A299= | Silent (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- HYDIN | c.13848T>C p.P4616= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV66642810; called by muse, mutect2, varscan2
- MDC1 | c.1569A>G p.T523= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV64528268; called by muse, mutect2, varscan2
- MLKL | c.717C>T p.S239= | Silent (SNP) | VAF 133/509 reads (26%) | catalogued as COSV58206820; called by muse, mutect2, varscan2
- PNO1 | c.688T>C p.L230= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs146981426; called by muse, mutect2, varscan2
- PTEN | c.624C>T p.G208= | Silent (SNP) | VAF 84/358 reads (23%) | catalogued as rs370162160, COSV64291105; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.1479A>G p.S493= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as COSV60392260; called by muse, mutect2, varscan2
- VILL | c.471C>T p.S157= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV52188479; called by muse, mutect2, varscan2
- ZFPM1 | c.1035G>A p.T345= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs758360400, COSV60326045; called by muse, mutect2, varscan2
- XIRP2 | c.*826_*830del | 3'UTR (DEL) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
